MMRF case MMRF_1518 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1cff19f6-baec-437c-a979-d963d43d4a20

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Dead; Days to death: 240 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.5 years (23,200 days); ISS stage: II; Days to last known disease status: 240 days; Days to last follow up: 240 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 98 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Doxorubicin; Regimen or line of therapy: First line of therapy; Days to treatment start: 98 days; Days to treatment end: 135 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 155 days; Days to treatment end: 158 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 157 days; Days to treatment end: 157 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 221 days; Days to treatment end: 240 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 240.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.33 mg/dL; Immunoglobulin G 31.3 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.77 µg/mL; Lactate Dehydrogenase 6.38 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 17.7 ×10⁹/L; Absolute Neutrophil 12.2 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 46 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 33 g/L; Total Protein 8.3 g/dL; Glucose 6.33 mmol/L; C-Reactive Protein 3.9 mg/dL.
- Day 71 (ECOG 2): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.98 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 1.63 µg/mL; Lactate Dehydrogenase 8.15 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 512 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 6.8 g/dL; Glucose 8.86 mmol/L.
- Day 190 (ECOG 2): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.26 mg/dL; Immunoglobulin G 10.4 g/L; Beta 2 Microglobulin 3.15 µg/mL; Lactate Dehydrogenase 6.52 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 6.17 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 5.12 mmol/L.

Other clinical attributes
- Day -12: Weight: 109 kg; Height: 159 cm.

Biospecimens (3 samples)
- Sample MMRF_1518_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 71 days.
- Sample MMRF_1518_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 190 days.
- Sample MMRF_1518_3_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 190 days.
